Somatic mutation profile of tumor specimen bebb15ad-03f1-4773-b3d4-2f78e3 (aliquot bebb15ad-03f1-4773-b3d4-2f78e3_D6_1) from CPTAC case 18BR006, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.2 years (22,721 days).
Specimen bebb15ad-03f1-4773-b3d4-2f78e3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28e5691b-5a3e-4aea-8a10-3d6f2cdc8d92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen a2e6e27a-79d3-47dd-b9b5-a16ee0 (Blood Derived Normal), aliquot a2e6e27a-79d3-47dd-b9b5-a16ee0_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/35254613-1aed-4b64-96be-2ba8b418325f

The open-access MAF lists 140 somatic variants for this specimen: 102 protein-altering or splice-affecting, 23 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 23, Frame Shift Del 5, Nonsense Mutation 5, 5'UTR 4, Splice Region 4, 5'Flank 3, RNA 3, 3'UTR 3, Splice Site 3, In Frame Del 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.3239T>C p.F1080S | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1370587865; called by muse, mutect2, varscan2
- AP2A2 | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 5/108 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as rs764112721; called by muse, mutect2
- BIN3 | c.525G>T p.K175N | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV52383816; called by muse, mutect2, varscan2
- CLASP1 | c.4153G>A p.A1385T | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); catalogued as COSV55318031; called by muse, mutect2
- CYTH4 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 67/167 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1179811351; called by muse, mutect2, varscan2
- DUSP11 | c.601C>T p.H201Y | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240908836; called by muse, mutect2, varscan2
- DUSP7 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1444636941; called by muse, mutect2
- EIF3K | c.32T>G p.V11G | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749037064; called by muse, mutect2, varscan2
- FLNC | c.25G>T p.D9Y | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57952989; called by muse, mutect2, varscan2
- FOS | c.141+1G>T p.X47_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV57839230; called by mutect2, varscan2
- GPLD1 | c.2096C>G p.S699C | Missense Mutation (SNP) | VAF 43/153 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as rs1270706504; called by muse, mutect2, varscan2
- GRIK2 | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59744393; called by muse, mutect2, varscan2
- H4C2 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs1296621230, COSV55138254, COSV99774715, COSV99774982; called by muse, mutect2
- ITPRID1 | c.2407G>T p.A803S | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV60074619; called by muse, mutect2
- KLHL24 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs376939080; called by muse, mutect2, varscan2
- MAN2C1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs748518057; called by muse, mutect2, varscan2
- MGAM | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 84/226 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV72073666; called by muse, mutect2, varscan2
- MYOF | c.1996C>T p.R666W | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs372369806, COSV63705822; called by muse, mutect2, varscan2
- NINL | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.211); catalogued as rs781098435; called by mutect2, varscan2
- OR6N2 | c.80T>A p.L27H | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59411724; called by muse, mutect2, varscan2
- PTPRD | c.4819G>A p.D1607N | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as rs1250220732; called by muse, mutect2
- SAMD12 | c.129C>G p.F43L | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV100125706; called by muse, mutect2, varscan2
- SPEN | c.4846C>T p.H1616Y | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV101005442; called by muse, mutect2
- THBD | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV101001882; called by muse, mutect2, varscan2
- ABCA8 | c.4233G>C p.E1411D | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.284); called by muse, mutect2
- ADAM11 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 32/147 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ADAMTS15 | c.552C>G p.I184M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); called by muse, mutect2
- ADCY1 | c.2333G>T p.G778V | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ALS2 | c.3136G>A p.D1046N | Missense Mutation (SNP) | VAF 130/413 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ANKRD27 | c.146C>G p.S49C | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ANKRD33 | c.-256A>T | Splice Region (SNP) | VAF 23/73 reads (32%) | called by muse, mutect2, varscan2
- AP5Z1 | c.488T>A p.L163H | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- CCNDBP1 | c.169_169+13del p.X57_splice | Splice Site (DEL) | VAF 28/84 reads (33%) | called by mutect2, pindel, varscan2
- CCR3 | c.661G>T p.G221* | Nonsense Mutation (SNP) | VAF 21/215 reads (10%) | called by muse, mutect2, varscan2
- CCT4 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- CFAP44 | c.3261A>T p.A1087= | Splice Region (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- CNOT6 | c.708_714del p.S237Rfs*14 | Frame Shift Del (DEL) | VAF 25/67 reads (37%) | called by mutect2, pindel, varscan2
- COL5A3 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.068); called by muse, mutect2
- COX5B | c.320A>G p.K107R | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- CXCL5 | c.237A>T p.E79D | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCHS2 | n.3893A>C | Splice Region (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- DIAPH2 | c.1077A>C p.K359N | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMC1 | c.647T>C p.I216T | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.112); called by muse, mutect2
- DNASE1L2 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 115/331 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4A2 | c.1146G>C p.K382N | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- EXT1 | c.920A>T p.H307L | Missense Mutation (SNP) | VAF 195/526 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- GCSAM | c.236C>G p.T79S | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR62 | c.304T>G p.C102G | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.482); called by muse, varscan2
- GRIP2 | c.3115-6_3142del p.X1039_splice (on ENST00000619221; = p.X942_splice on NM_001080423.4) | Splice Site (DEL) | VAF 14/128 reads (11%) | called by mutect2, pindel, varscan2
- GRXCR1 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 26/343 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- H6PD | c.441_450del p.F147Lfs*57 | Frame Shift Del (DEL) | VAF 58/243 reads (24%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.107G>C p.G36A | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2
- INTU | c.2565G>T p.K855N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- IRS4 | c.1277T>C p.V426A | Missense Mutation (SNP) | VAF 174/511 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA4 | c.1141G>T p.D381Y | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITGAV | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ITIH5 | c.1144A>G p.R382G | Missense Mutation (SNP) | VAF 18/324 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2
- JADE2 | c.1464G>T p.R488S | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- JAG2 | c.964del p.T322Rfs*120 | Frame Shift Del (DEL) | VAF 145/534 reads (27%) | called by mutect2, pindel, varscan2
- KLHL24 | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 26/201 reads (13%) | called by muse, mutect2, varscan2
- KPNA7 | c.652A>T p.N218Y | Missense Mutation (SNP) | VAF 73/215 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMC3 | c.3682G>T p.V1228L | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- MCOLN1 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 15/414 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2
- METTL24 | c.824G>A p.W275* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | called by muse, mutect2, varscan2
- MRC2 | c.4114A>T p.I1372F | Missense Mutation (SNP) | VAF 12/263 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- MYOCD | c.926A>C p.Q309P | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, varscan2
- NKX2-2 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 81/436 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUMA1 | c.579del p.N194Tfs*23 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | called by pindel, varscan2*
- OR2W1 | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.104); called by muse, mutect2
- OR6K2 | c.56A>C p.Y19S | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2
- PARP9 | c.1667G>A p.R556K | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PCDH11X | c.175A>C p.T59P | Missense Mutation (SNP) | VAF 14/441 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2
- PDE1B | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 58/147 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PEX5L | c.1532G>A p.W511* | Nonsense Mutation (SNP) | VAF 42/126 reads (33%) | called by muse, mutect2, varscan2
- PMEPA1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 35/411 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- PRKCI | c.99C>G p.R33= | Splice Region (SNP) | VAF 28/92 reads (30%) | called by mutect2, varscan2
- PRPF3 | c.-23_5del | Translation Start Site (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- QSOX1 | c.1693G>T p.A565S | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.021); called by muse, mutect2
- RAB3GAP2 | c.1576G>A p.D526N | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- REG1B | c.444del p.K148Nfs*23 | Frame Shift Del (DEL) | VAF 38/141 reads (27%) | called by mutect2, pindel, varscan2
- RPGRIP1L | c.3736G>A p.D1246N | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); called by muse, mutect2
- RYR1 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 31/371 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by muse, mutect2
- RYR1 | c.1358C>G p.P453R | Missense Mutation (SNP) | VAF 30/361 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- SF3B1 | c.3416_3430del p.P1139_V1143del | In Frame Del (DEL) | VAF 50/184 reads (27%) | called by mutect2, pindel, varscan2
- SH2D4A | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SH3RF3 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLC25A47 | c.907_921del p.A303_L307del | In Frame Del (DEL) | VAF 33/239 reads (14%) | called by mutect2, pindel, varscan2
- SON | c.4987G>A p.D1663N | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- SOWAHA | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- SPTLC1 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 77/268 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- STAT2 | c.1786G>C p.G596R | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUMO1 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- TBCK | c.1873C>A p.P625T (on ENST00000273980 / NM_001163436.4; = p.P562T on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TMEM43 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 76/516 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.88111A>G p.K29371E (on ENST00000591111; = p.K21947E on NM_003319.4) | Missense Mutation (SNP) | VAF 253/773 reads (33%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WDFY4 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- WDR87 | c.2452A>T p.R818W | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- WWOX | c.1125C>A p.Y375* | Nonsense Mutation (SNP) | VAF 82/344 reads (24%) | called by muse, mutect2, varscan2
- YWHAG | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 138/407 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF219 | c.267C>A p.H89Q | Missense Mutation (SNP) | VAF 41/219 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ZNF362 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- ZNF451 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- ADAMTSL1 | c.906G>A p.R302= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV52815698, COSV52819693; called by muse, mutect2
- AGK | c.1068C>T p.P356= | Silent (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- APOB | c.3096C>T p.T1032= | Silent (SNP) | VAF 28/352 reads (8%) | called by muse, mutect2
- ASMTL | c.384C>T p.V128= | Silent (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- BCS1L | c.129C>T p.F43= | Silent (SNP) | VAF 167/546 reads (31%) | called by muse, mutect2, varscan2
- CCDC22 | c.117C>T p.V39= | Silent (SNP) | VAF 50/146 reads (34%) | called by muse, mutect2, varscan2
- FAM155B | c.597C>T p.C199= | Silent (SNP) | VAF 9/221 reads (4%) | called by muse, mutect2
- GIN1 | c.1542A>T p.S514= | Silent (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- GMPS | c.135G>A p.V45= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs770992967; called by muse, mutect2, varscan2
- HR | c.633G>C p.P211= | Silent (SNP) | VAF 21/252 reads (8%) | catalogued as COSV57193991; called by muse, mutect2
- KIAA1671 | c.1716G>A p.T572= | Silent (SNP) | VAF 37/205 reads (18%) | catalogued as rs1270006660; called by muse, mutect2, varscan2
- LCT | c.402G>A p.Q134= | Silent (SNP) | VAF 24/516 reads (5%) | called by muse, mutect2
- MUC4 | c.16047C>T p.F5349= (on ENST00000463781 / NM_018406.7; = p.F1113= on NM_004532.6) | Silent (SNP) | VAF 26/298 reads (9%) | called by muse, mutect2
- MYO5C | c.3222C>T p.F1074= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as rs773376914, COSV55902641; called by muse, mutect2, varscan2
- NOTCH3 | c.1785C>T p.G595= | Silent (SNP) | VAF 96/514 reads (19%) | catalogued as COSV54639661; called by muse, mutect2, varscan2
- OBSCN | c.4797G>A p.A1599= | Silent (SNP) | VAF 73/460 reads (16%) | catalogued as rs750630188, COSV99486036; called by muse, varscan2
- OR10X1 | c.732C>T p.I244= | Silent (SNP) | VAF 162/432 reads (38%) | catalogued as COSV63767602; called by muse, mutect2, varscan2
- OSM | c.498G>A p.T166= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs959813707, COSV99304318; called by muse, mutect2
- PLPP7 | c.312G>A p.A104= | Silent (SNP) | VAF 35/154 reads (23%) | catalogued as rs371251864; called by muse, mutect2, varscan2
- POM121L12 | c.72A>G p.Q24= | Silent (SNP) | VAF 62/212 reads (29%) | catalogued as rs755474193; called by muse, mutect2, varscan2
- PTPRB | c.5820A>G p.R1940= | Silent (SNP) | VAF 61/168 reads (36%) | called by muse, mutect2, varscan2
- RFX2 | c.1743G>C p.L581= | Silent (SNP) | VAF 7/137 reads (5%) | called by muse, mutect2
- TAP1 | c.171C>T p.V57= | Silent (SNP) | VAF 63/170 reads (37%) | called by muse, mutect2, varscan2
- AC068587.8 | n.55G>A | RNA (SNP) | VAF 12/98 reads (12%) | called by muse, mutect2
- AC093334.1 | n.14G>T | RNA (SNP) | VAF 24/135 reads (18%) | called by muse, mutect2, varscan2
- ACTG1 | c.-405C>G | 5'UTR (SNP) | VAF 16/66 reads (24%) | catalogued as rs75739711; called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097095 C>T | 3'Flank (SNP) | VAF 20/188 reads (11%) | called by muse, varscan2
- ALG11 | c.*214G>C | 3'UTR (SNP) | VAF 56/221 reads (25%) | called by muse, mutect2, varscan2
- DPPA4 | c.-15G>A | 5'UTR (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- EFEMP1 | c.*11G>C | 3'UTR (SNP) | VAF 11/232 reads (5%) | called by muse, mutect2
- HIPK1 | chr1:113929381 C>T | 5'Flank (SNP) | VAF 38/306 reads (12%) | called by muse, mutect2, varscan2
- HIPK1 | chr1:113929509 C>G | 5'Flank (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2, varscan2
- LHX1 | c.-431G>T | 5'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- MAN1B1 | c.328+127A>C | Intron (SNP) | VAF 132/261 reads (51%) | called by muse, mutect2, varscan2
- MIR29B2 | n.68C>A | RNA (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- PTGES2 | chr9:128128766 A>T | 5'Flank (SNP) | VAF 55/229 reads (24%) | called by muse, mutect2, varscan2
- TRGV3 | c.-6G>T | 5'UTR (SNP) | VAF 26/102 reads (25%) | called by muse, mutect2, varscan2
- VCX3B | c.*33C>G | 3'UTR (SNP) | VAF 40/440 reads (9%) | catalogued as rs764620116, COSV101123765; called by muse, mutect2
